Somatic mutation profile of tumor specimen MP2PRT-PAVMVV-TBP1-A (aliquot MP2PRT-PAVMVV-TBP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVMVV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,393 days).
Specimen MP2PRT-PAVMVV-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6bf39de2-6f77-4b22-a98e-941acaa1ccb7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVMVV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVMVV-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3baea85-151d-42b7-a523-8416ac220cca

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 9, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 34/384 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- H2BC12 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 62/551 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.124); catalogued as COSV100804681, COSV63616685; called by muse, mutect2, varscan2
- HTR1A | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 51/494 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100109341; called by muse, mutect2, varscan2
- KCNN2 | c.82G>A p.D28N (on ENST00000264773; = p.D240N on NM_021614.4) | Missense Mutation (SNP) | VAF 70/682 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.776); catalogued as rs772670260; called by muse, varscan2
- PTPRU | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 30/399 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs771105941, COSV60533354, COSV60538710; called by muse, mutect2
- PTPRZ1 | c.5089G>A p.G1697R | Missense Mutation (SNP) | VAF 35/264 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.463); catalogued as rs147762028; called by muse, mutect2, varscan2
- RFPL1 | c.595G>C p.E199Q | Missense Mutation (SNP) | VAF 70/605 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV62977456; called by muse, mutect2, varscan2
- TMEM202 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 67/531 reads (13%) | catalogued as rs368153584, COSV100499222; called by muse, mutect2, varscan2
- GFM1 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 8/181 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.391); called by muse, mutect2
- RECQL | c.1165C>T p.H389Y | Missense Mutation (SNP) | VAF 35/286 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- AGAP3 | c.1134C>T p.S378= (on ENST00000622464; = p.S414= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/337 reads (11%) | catalogued as rs201990368, COSV58996889; called by mutect2, varscan2
- CUBN | c.10077G>A p.S3359= | Silent (SNP) | VAF 31/356 reads (9%) | catalogued as rs147563157, COSV100912533, COSV100912978; called by muse, mutect2
- E2F8 | c.1530G>A p.L510= | Silent (SNP) | VAF 69/565 reads (12%) | called by muse, mutect2, varscan2
- MUC16 | c.23343C>T p.S7781= | Silent (SNP) | VAF 63/533 reads (12%) | called by muse, mutect2, varscan2
